Somatic mutation profile of tumor specimen TCGA-AX-A1CJ-01A (aliquot TCGA-AX-A1CJ-01A-11D-A135-09) from TCGA case TCGA-AX-A1CJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 59.3 years (21,655 days).
Specimen TCGA-AX-A1CJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35620cdd-65a1-43b4-9a30-99225a00a514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CJ-11A (Solid Tissue Normal), aliquot TCGA-AX-A1CJ-11A-11D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02283f08-4787-4477-9927-2faf95458ab1

The open-access MAF lists 70 somatic variants for this specimen: 45 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 22, Frame Shift Del 6, 5'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1, RNA 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 23/51 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 39/64 reads (61%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.465dup p.T156Yfs*6 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs1180724229; called by mutect2, varscan2
- ADAR | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.253); catalogued as COSV52716300, COSV99425809; called by muse, mutect2, varscan2
- APOBEC1 | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV99981060; called by muse, mutect2, varscan2
- CD40LG | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV101033467; called by muse, mutect2, varscan2
- CDKN1B | c.410del p.P137Rfs*8 | Frame Shift Del (DEL) | VAF 20/41 reads (49%) | catalogued as rs1328655695, COSV99964122; called by mutect2, pindel, varscan2
- CLCNKA | c.1444A>T p.I482F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100510001; called by muse, mutect2, varscan2
- CLIP2 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs370792041, COSV99791347; called by muse, mutect2, varscan2
- CPT1C | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as rs1568517427, COSV99773362; called by muse, mutect2
- DRD5 | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100431691; called by muse, mutect2, varscan2
- EFNB3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs566715199, COSV99872684, COSV99873059; called by muse, mutect2, varscan2
- EPHA3 | c.563del p.A188Vfs*8 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as COSV60699190; called by mutect2, pindel, varscan2
- EPHA6 | c.3017G>T p.C1006F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67590461; called by muse, mutect2, varscan2
- ESD | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs143158972, COSV101099119; called by muse, mutect2, varscan2
- FANK1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs145929999; called by muse, mutect2, varscan2
- FAT3 | c.9644C>T p.S3215F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV53186941; called by muse, mutect2, varscan2
- GALNT15 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as rs755282595, COSV100327515; called by muse, mutect2, varscan2
- GATA5 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99435761; called by muse, mutect2, varscan2
- GPRASP1 | c.4041C>A p.N1347K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV100850969, COSV64356199; called by muse, mutect2
- IPO8 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99805088; called by muse, mutect2, varscan2
- IRF9 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778462458, COSV60704463; called by muse, mutect2, varscan2
- KAT6A | c.4982C>T p.P1661L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as rs544240461, COSV99704838; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs753332734; called by mutect2, varscan2
- KMT2D | c.7618C>T p.Q2540* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99979938; called by muse, mutect2, varscan2
- LAMA2 | c.7514C>T p.P2505L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764060943, COSV70340393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBOAT7 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396109520, COSV99824751; called by muse, mutect2, varscan2
- OTOGL | c.6230G>T p.C2077F (on ENST00000547103; = p.C2068F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV100087079; called by muse, mutect2, varscan2
- PSMF1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV99850411; called by muse, mutect2, varscan2
- RMND1 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100323609; called by muse, mutect2, varscan2
- RNF123 | c.2341A>G p.M781V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs572797367, COSV100570562; called by muse, mutect2, varscan2
- SIGLEC14 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as rs759989219, COSV55778956; called by muse, mutect2, varscan2
- SLC12A4 | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766344864, COSV100311647; called by muse, mutect2, varscan2
- TCHH | c.4621C>G p.R1541G | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV100914965; called by muse, mutect2, varscan2
- TDRP | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1346805288, COSV100138457; called by muse, mutect2, varscan2
- TFB1M | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.26); catalogued as rs772923848, COSV100905177; called by muse, mutect2, varscan2
- TMTC2 | c.992C>A p.P331Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV58283710; called by muse, mutect2, varscan2
- WDTC1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757186775, COSV100088724; called by muse, mutect2, varscan2
- WIPF1 | c.1383T>A p.D461E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV55812728, COSV99768440; called by muse, mutect2, varscan2
- XYLT1 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1317696198, COSV54476254, COSV99762862; called by muse, mutect2, varscan2
- ZNF292 | c.7945G>A p.E2649K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs752678527, COSV60539773; called by muse, mutect2, varscan2
- ZNF611 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1463900197, COSV100160184; called by muse, mutect2, varscan2
- NEGR1 | c.878_880delinsC p.G293Afs*20 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by pindel, varscan2*
- PLPPR5 | c.307del p.T103Lfs*3 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ZNRF3 | c.989_991dup p.C330_P331insR (on ENST00000544604 / NM_001206998.2; = p.C230_P231insR on NM_032173.3) | In Frame Ins (INS) | VAF 21/34 reads (62%) | called by mutect2, pindel, varscan2
- BRICD5 | c.723C>T p.I241= (on ENST00000562360; = p.I209= on NM_182563.3) | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs561967169, COSV57031432; called by muse, mutect2, varscan2
- C2orf16 | c.3204G>A p.K1068= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1558458205, COSV100820741; called by muse, mutect2, varscan2
- CAMK1D | c.576C>T p.V192= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV66608920; called by muse, mutect2, varscan2
- CAMKK1 | c.1488C>T p.P496= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs371095701; called by muse, mutect2
- CYP1A1 | c.1293G>T p.R431= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101122268; called by muse, mutect2, varscan2
- EGFL6 | c.1057C>T p.L353= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100789870; called by muse, mutect2, varscan2
- FAM166C | c.87C>T p.H29= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs753762077, COSV100297165; called by muse, mutect2, varscan2
- FNIP2 | c.1215C>T p.S405= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs756191047, COSV52437955; called by muse, mutect2, varscan2
- IRX4 | c.213C>T p.G71= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99180786; called by muse, mutect2, varscan2
- ITFG1 | c.201G>A p.L67= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs765465781, COSV100066513; called by muse, mutect2, varscan2
- KCNS2 | c.117C>T p.P39= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs749461522, COSV99751028; called by muse, mutect2, varscan2
- KCTD8 | c.786G>A p.P262= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs1405428652, COSV100759266; called by muse, mutect2, varscan2
- NTNG2 | c.567C>T p.S189= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100647387; called by muse, mutect2, varscan2
- PCDHA11 | c.2199G>A p.P733= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV56477238; called by muse, mutect2, varscan2
- PCDHA12 | c.2184C>T p.T728= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs782196097, COSV56482972; called by muse, mutect2, varscan2
- PDE4A | c.1563C>A p.I521= (on ENST00000380702 / NM_001111307.2; = p.I282= on NM_006202.3) | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99533952; called by mutect2, varscan2
- PNPLA6 | c.1980C>T p.G660= (on ENST00000414982 / NM_001166111.2; = p.G612= on NM_006702.5) | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs1201757918, COSV99653484; called by muse, mutect2, varscan2
- PRRC2B | c.591A>G p.P197= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV61939163; called by muse, mutect2, varscan2
- SLC9A6 | c.1668G>A p.P556= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1060504687, COSV100857883; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRAPPC2L | c.261C>T p.S87= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs749504692, COSV99243077; called by muse, mutect2, varscan2
- ZIK1 | c.9G>A p.A3= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs370437164, COSV100277438; called by muse, mutect2, varscan2
- ZNF112 | c.2271C>T p.G757= (on ENST00000337401 / NM_001083335.2; = p.G751= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100495652; called by muse, mutect2, varscan2
- ACSM3 | c.639-51A>T | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as rs201158405, COSV99184287; called by muse, mutect2, varscan2
- MIR154 | n.25G>A | RNA (SNP) | VAF 28/79 reads (35%) | catalogued as rs575922548; called by muse, mutect2, varscan2
- SREK1 | c.-264G>T | 5'UTR (SNP) | VAF 52/136 reads (38%) | catalogued as COSV52335330, COSV99398514; called by muse, mutect2, varscan2
